Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AAXU, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AAXU-01A (Primary Tumor).

SPEC #: Status: Obtained: Received:

CLINICAL HISTORY:

233.1

SPECIMEN/PROCEDURE:

1. CERVIX - 4:00

IMPRESSION:

CERVIX, 4 O'CLOCK, BIOPSY:

Invasive squamous cell carcinoma, large cell nonkeratinizing type, moderately differentiated.

Dictated by:

Entered:

COMMENT:

The case is reviewed with

Entered:

, who concurs.

ICD O-3
(carcinoma), squamous cell, large
cell, non-keratinizing NOS 807213
Site: Cervix NOS C53.9
J2 6/3/14

GROSS DESCRIPTION:

1. Received in formalin labeled with the patient's name and succeed 4 o'clock. Received is a pale pink to red tan tissue fragment that is 0.6 x 0.5 x 0.2 cm. The specimen is entirely submitted in one cassette.

Dictated by:

Entered:

CPT Codes:

CERVICAL BIOPSY/88305

ICD9 Codes:

180.9

Electronically Signed by: _____

** END OF REPORT **

Source: NCI Genomic Data Commons file 02f43dbb-9339-4f7e-a0f0-df26ebda74e4 (TCGA-ZJ-AAXU.6A8C28EF-7774-492D-99D0-C197662699AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).